CCDI case PBBUCU — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Connective, subcutaneous and other soft tissues.
https://portal.gdc.cancer.gov/cases/348d2368-3b2f-41ae-99d3-09fcd340003e

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Dermatofibrosarcoma protuberans, NOS: ICD-O-3 morphology code: 8832/3; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of pelvis; Age at diagnosis: 8.2 years (2,990 days).

Biospecimens (1 sample)
- Sample 0DHTE3: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
